Gene-level copy-number profile of tumor specimen TCGA-34-2604-01A from TCGA case TCGA-34-2604, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.7 years (29,827 days).
Specimen TCGA-34-2604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.abdcd279-fdca-46dd-9d60-94988efd5ecc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-2604-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/782f3aba-a769-485c-aac5-08fbfa87e060

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,423; copy number 2: 21,188; copy number 3: 21,725; copy number 4: 10,329; copy number 5: 650; copy number 6: 413; copy number 8: 974; copy number 9: 118.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-2604-01A-01D-0844-01): tumor purity 0.24, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,092 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,944,428–198,222,513, 974 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr22:19,447,893–21,471,269, 118 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,146. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
